CCDI case PBBURC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/691a6b8f-6a8f-4af4-b85d-1a3b3b1b0a79

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,277 days).

Biospecimens (3 samples)
- Sample 0DHX1W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHX2M: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHX2V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
